Gene-level copy-number profile of tumor specimen C3L-06340-02 from CPTAC case C3L-06340, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 60.1 years (21,944 days).
Specimen C3L-06340-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 181d046a-67c1-4694-8760-a7a7315cccfc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06340-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/af023735-1ced-4c12-8eb0-05670afe5495

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 7,251; copy number 2: 40,910; copy number 3: 7,329; copy number 4: 1,763; copy number 5: 1,119; copy number 6: 12; copy number 7: 4; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:80,534,978–80,584,363, 1 gene (within-gene range 0–2): AL136234.1.
- chr6:45,197,674–45,197,770, 1 gene (within-gene range 0–2): MIR586.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,141 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,688,463–48,091,736, 7 genes, copy number 5: LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P.
- chr1:56,145,721–62,451,804, 75 genes, copy number 5–6 (broad region; genes not listed).
- chr1:62,784,132–63,660,245, 32 genes, copy number 5: ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P.
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr7:95,772,506–100,906,572, 169 genes, copy number 5 (broad region; genes not listed).
- chr7:102,327,256–146,050,366, 842 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,621,379, 5 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr21:10,612,455–13,067,033, 6 genes, copy number 8: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 7,248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
